Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6676, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6676-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Clinical Diagnosis & History:

[REDACTED] year old male 5 cm mass seen in descending colon on colonoscopy 45 cm from anal verge.

Specimens Submitted:

- 1: Sigmoid colon; resection
- 2: Distal ring
- 3: Proximal ring

DIAGNOSIS:

- 1. Sigmoid colon; resection:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Sigmoid colon

Tumor Size:

Length is 2.5 cm

Width is 2.0 cm

Maximal thickness is 1.5 cm

Tumor Budding:

Focal

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Tubular adenoma

Deepest Tumor Invasion:

Muscularis propria

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Not identified

Large Venous Invasion:

Identified

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):

** Continued on next page **

[page 2 of 4]
Not Identified

Non-Neoplastic Bowel:

Unremarkable

Lymph Nodes:

Total number examined: 17

One lymph node contains metastatic carcinoma, consistent with prostatic origin, see comment.

Tumor Staging (AJCC 7th Edition):

pT2 (Tumor invades muscularis propria)

Lymph Node Stage (AJCC 7th Edition):

N0 (No regional lymph node metastasis)

Comment: Immunohistochemical stains show that the tumor cells in the lymph node are positive for PSA, while negative for CK7, CK20, CDX-2, TTF-1, chromogranin, and synaptophysin, consistent with a prostate origin.

2. Colon, distal ring; excision:
-Benign colonic tissue with hyperplastic changes.
3. Colon, proximal ring; excision:
-Benign colonic tissue.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1) The specimen is received fresh and is labeled "sigmoid colon". It consists of an unoriented segment of sigmoid colon that measures 26 x 6 cm. The serosal surface is unremarkable. The radial resection margin is inked black and the specimen is opened to reveal a polypoid tumor that is located 2.4 cm from one margin and 21 cm from the opposite margin. The tumor measures 2.5 cm in length and 2 cm in width. Serial sectioning reveals that the tumor maximum thickness is 1.5 cm. The remaining mucosa is unremarkable. Pericolonic adipose tissue spans the entire length of the specimen with a maximum thickness of 12 cm. It is submitted for lymph node dissection and thoroughly examined for lymph nodes, and all possible nodes are submitted. Representative sections are submitted. TPS is submitted.

** Continued on next page **

[page 3 of 4]
Summary of sections:

M1 - margin closer to the tumor
M2 - margin farther from the tumor
T - tumor
U - uninvolved mucosa
LN - lymph nodes
BLN - bisected lymph node

2) The specimen is received in formalin, labeled "distal ring" and consists of a ring of pink tan soft tissue measuring 2.5 x 1.8 x 1.3 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed, and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

3) The specimen is received in formalin, labeled "proximal ring" and consists of a ring of pink tan soft tissue measuring 2.0 x 1.8 x 1.4 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan and focally hemorrhagic. The sutures and staples are removed, and the soft tissue is entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Sigmoid colon; resection

Block	Sect.	Site	PCs
6		LN	16
1		M1	1
1		M2	2
4		T	4
1		U	1

Part 2: Distal ring

Block	Sect.	Site	PCs
2		U	0

** Continued on next page **

[page 4 of 4]
[REDACTED]

Part 3: Proximal ring

Block	Sect.	Site	PCs
2		U	0

** End of Report **

Source: NCI Genomic Data Commons file acdd6e9e-4ef0-46ea-913d-94b0066d094d (TCGA-CM-6676.1D53F325-F6F5-474E-9B52-0B45AEF1DFF8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).